Somatic mutation profile of tumor specimen TCGA-C5-A7X3-01A (aliquot TCGA-C5-A7X3-01A-11D-A351-09) from TCGA case TCGA-C5-A7X3, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 70.3 years (25,665 days).
Specimen TCGA-C5-A7X3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00a5dbbe-4695-4563-9800-8645f50b99b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A7X3-10A (Blood Derived Normal), aliquot TCGA-C5-A7X3-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/117b6d6c-f737-4650-94de-fad4321e51d7

The open-access MAF lists 73 somatic variants for this specimen: 57 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 13, Nonsense Mutation 5, Splice Site 2, Intron 1, 3'Flank 1, In Frame Ins 1, 3'UTR 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFMID | c.50_52del p.K17del | In Frame Del (DEL) | VAF 14/51 reads (27%) | catalogued as rs746638950; called by pindel, varscan2
- ARFIP1 | c.985C>T p.Q329* (on ENST00000353617 / NM_001287432.1; = p.Q297* on NM_014447.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 5/50 reads (10%) | catalogued as rs777740272, COSV61885582; called by muse, mutect2, varscan2
- ATXN2L | c.1507C>T p.P503S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs772634261, COSV57375201; called by muse, mutect2, varscan2
- BAZ2A | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs767981157, COSV51640463; called by muse, mutect2, varscan2
- CD300C | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.267); catalogued as COSV58171053; called by muse, mutect2
- CFAP20DC | c.2071G>T p.A691S (on ENST00000482387 / NM_001351530.2; = p.A440S on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV55924115; called by muse, mutect2, varscan2
- CHL1 | c.2558A>T p.K853I (on ENST00000397491 / NM_001253387.1; = p.K869I on NM_006614.4) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV99850370; called by muse, mutect2
- CLCN1 | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.99); PolyPhen benign (0.021); catalogued as rs139158852; called by muse, mutect2, varscan2
- CLTB | c.526G>A p.E176K (on ENST00000310418 / NM_007097.5; = p.E158K on NM_001834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs928571864, COSV51257512; called by muse, mutect2, varscan2
- CRIM1 | c.1778G>C p.R593T | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV54869046; called by muse, mutect2, varscan2
- DDB1 | c.2833-1G>A p.X945_splice | Splice Site (SNP) | VAF 5/45 reads (11%) | catalogued as COSV57104588; called by muse, mutect2, varscan2
- DENND4C | c.5629A>G p.I1877V (on ENST00000434457 / NM_001330640.2; = p.I1828V on NM_017925.7) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.072); catalogued as rs542086159, COSV63009362; called by muse, mutect2, varscan2
- ELOA2 | c.1761T>A p.N587K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV55303814; called by muse, mutect2, varscan2
- FANCA | c.2909C>T p.S970L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99981247; called by muse, mutect2, varscan2
- FMN2 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as rs1244766156, COSV60442383; called by muse, mutect2, varscan2
- FN3KRP | c.683C>G p.S228C | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as COSV53930547; called by muse, mutect2, varscan2
- FZD4 | c.1242C>G p.F414L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.679); catalogued as rs1406405036, COSV101536027; called by muse, mutect2, varscan2
- GABRE | c.1367A>T p.Y456F | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.996); catalogued as COSV64820548; called by muse, mutect2, varscan2
- GAD1 | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as COSV60153376; called by muse, mutect2, varscan2
- GOLGB1 | c.1750A>G p.R584G | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.053); catalogued as rs1218377282, COSV61468499; called by muse, mutect2, varscan2
- GRSF1 | c.482G>A p.C161Y | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV54657340; called by muse, mutect2
- GTPBP1 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53286569; called by muse, mutect2, varscan2
- HYOU1 | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1263148051, COSV68216780; called by muse, mutect2, varscan2
- IGHV2-70 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs10144844; called by muse, varscan2
- IL17C | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.588); catalogued as rs753393935, COSV54919013; called by muse, mutect2, varscan2
- INO80 | c.4349G>A p.R1450Q | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as COSV62739494; called by mutect2, varscan2
- INPP5D | c.3131G>A p.R1044Q (on ENST00000445964 / NM_001017915.3; = p.R1043Q on NM_005541.5) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.267); catalogued as rs201032928; called by muse, mutect2, varscan2
- ITGA5 | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99516394; called by muse, varscan2
- ITGA5 | c.1872G>T p.R624S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.226); catalogued as COSV53219526; called by muse, varscan2
- KCNH4 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.136); catalogued as COSV52919772; called by mutect2, varscan2
- KRTAP11-1 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV60094998; called by muse, mutect2, varscan2
- LIFR | c.727A>G p.N243D | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV54695481; called by muse, mutect2, varscan2
- LIPG | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs756501637, COSV54296849; called by muse, mutect2
- MDP1 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51661196; called by muse, mutect2, varscan2
- MRPL37 | c.1249C>G p.L417V | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as COSV60322208; called by muse, mutect2, varscan2
- MYRF | c.2162C>T p.S721L (on ENST00000278836 / NM_001127392.3; = p.S712L on NM_013279.4) | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs985424827, COSV53887478; called by muse, mutect2, varscan2
- NCL | c.1811G>A p.R604Q | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.557); catalogued as COSV100502151; called by muse, mutect2
- NOTCH1 | c.1300G>T p.G434C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53037080; called by muse, mutect2, varscan2
- NUTM1 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as COSV61546098, COSV61547903; called by mutect2, varscan2
- PKD1 | c.9149C>A p.A3050D | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51921272; called by muse, mutect2, varscan2
- RUBCN | c.1847+1G>C p.X616_splice | Splice Site (SNP) | VAF 4/52 reads (8%) | catalogued as COSV99583450; called by muse, mutect2
- SCN10A | c.2746C>T p.R916W | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370208223; called by muse, mutect2, varscan2
- SCRIB | c.3674C>G p.S1225C | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV57590591; called by muse, mutect2, varscan2
- SERPINB1 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV66313834; called by muse, mutect2, varscan2
- SMC1A | c.1154G>C p.R385T | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.178); catalogued as COSV59130651; called by muse, mutect2
- SMG1 | c.7501C>T p.Q2501* | Nonsense Mutation (SNP) | VAF 5/63 reads (8%) | catalogued as COSV101245342; called by muse, mutect2
- SMS | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 10/75 reads (13%) | catalogued as COSV65114811; called by muse, mutect2, varscan2
- STK11 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.071); catalogued as COSV58825094, COSV58826380; called by muse, mutect2, varscan2
- TNNI3K | c.2441C>A p.S814Y | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV58560614; called by muse, mutect2, varscan2
- TOR1AIP1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.121); catalogued as rs1472497370, COSV54870827; called by muse, mutect2, varscan2
- UCK1 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | catalogued as rs576279404, COSV64736000; called by muse, mutect2, varscan2
- VN1R1 | c.483G>C p.K161N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV100320605; called by muse, mutect2, varscan2
- VN1R1 | c.359G>C p.G120A | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.695); catalogued as COSV58091478; called by muse, mutect2, varscan2
- ZNF829 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 15/106 reads (14%) | catalogued as rs764501501, COSV101199727, COSV66986684; called by muse, mutect2, varscan2
- KRT85 | c.251_254del p.S84Wfs*35 | Frame Shift Del (DEL) | VAF 23/58 reads (40%) | called by mutect2, pindel, varscan2
- TCF7L2 | c.537_539dup p.P180dup (on ENST00000355995 / NM_001367943.1; = p.P157dup on NM_030756.5) | In Frame Ins (INS) | VAF 5/20 reads (25%) | called by mutect2, pindel, varscan2
- TRAV20 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.435); called by muse, mutect2
- ARMC3 | c.1998A>C p.G666= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV99957602; called by muse, mutect2
- CDH17 | c.1614T>G p.P538= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV50333994; called by muse, mutect2, varscan2
- CHTF18 | c.399G>A p.P133= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs368449098, COSV50101176; called by mutect2, varscan2
- FOXP1 | c.771A>T p.T257= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as rs769711833, COSV59548397; called by muse, mutect2, varscan2
- LRCH1 | c.2061C>T p.L687= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs750942808, COSV60850552; called by muse, mutect2, varscan2
- MUC5B | c.2349C>T p.C783= | Silent (SNP) | VAF 35/173 reads (20%) | catalogued as rs1160023568, COSV71594253; called by muse, mutect2, varscan2
- RELB | c.1266G>C p.L422= | Silent (SNP) | VAF 13/129 reads (10%) | catalogued as COSV55511820; called by muse, mutect2
- RNF213 | c.6327G>A p.R2109= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV60404095, COSV60410187; called by muse, mutect2, varscan2
- SEMA3G | c.273G>A p.R91= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV51597052; called by muse, mutect2, varscan2
- SPANXN1 | c.165C>T p.C55= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as rs782601684, COSV100979463, COSV65122993; called by muse, mutect2, varscan2
- TNKS | c.1063C>T p.L355= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as rs1260404705, COSV60063045; called by muse, mutect2, varscan2
- TNNT1 | c.243C>T p.L81= | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- ZNF496 | c.336G>A p.Q112= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV54180136; called by muse, mutect2, varscan2
- BRMS1 | c.*83A>G | 3'UTR (SNP) | VAF 11/56 reads (20%) | catalogued as COSV104409870, COSV60927859; called by muse, mutect2, varscan2
- DIPK1B | chr9:136726876 ins A | 3'Flank (INS) | VAF 18/48 reads (38%) | called by mutect2, pindel, varscan2
- RAP1GAP | c.-149+4027C>T | Intron (SNP) | VAF 11/49 reads (22%) | catalogued as COSV58743040; called by muse, mutect2, varscan2
